MMRF case MMRF_1349 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8a0f04c5-3e9e-4869-a9e6-758f4f2e83ab

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Dead; Days to death: 1,150 days (3.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.0 years (31,055 days); ISS stage: III; Days to last known disease status: 1,150 days (3.1 years); Days to last follow up: 1,150 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 508 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 512 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,150.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 296 mg/dL; Immunoglobulin G 3.45 g/L; Immunoglobulin A 35.1 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 10.4 µg/mL; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 477 µmol/L; Blood Urea Nitrogen 23.9 mmol/L; Calcium 2.95 mmol/L; Albumin 28 g/L; Total Protein 10.1 g/dL; Glucose 9.9 mmol/L.
- Day 92: M Protein 0.4 g/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 5.07 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.4 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 260 (ECOG 1): M Protein 0.4 g/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 3.43 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 310 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 9.02 mmol/L.
- Day 372 (ECOG 1): Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 14.1 mmol/L.
- Day 470 (ECOG 1): M Protein 0 g/dL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 9.08 mmol/L.
- Day 512 (ECOG 1): Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 12.3 mmol/L.
- Day 592 (ECOG 1): M Protein 0 g/dL; Beta 2 Microglobulin 3.6 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 9.3 mmol/L.
- Day 679 (ECOG 1): M Protein 0 g/dL; Beta 2 Microglobulin 3.5 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 8.64 mmol/L.
- Day 800 (ECOG 1): M Protein 1 g/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 6.8 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 5.5 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.03 mmol/L; Albumin 27 g/L; Total Protein 5.8 g/dL; Glucose 6.6 mmol/L.
- Day 1,078 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 73.2 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 14.8 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 5.5 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 7.8 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -2: Weight: 59 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1349_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1349_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
